Gene-level copy-number profile of tumor specimen TCGA-04-1654-01A from TCGA case TCGA-04-1654, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 69.5 years (25,387 days).
Specimen TCGA-04-1654-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.7f9a9102-1105-4cbf-8381-a7f45cb26878.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1654-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c793e3fd-3255-4a42-be12-4772d948caa9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 15,300; copy number 2: 36,521; copy number 3: 6,496; copy number 4: 1,207; copy number 5: 48; copy number 6: 231.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-04-1654-01): tumor purity 0.88, ploidy 1.94, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:116,443,555–116,574,823, 3 genes (within-gene range 0–1): SEMA6A, SEMA6A-AS1, RPS14P8.
- chr16:79,077,376–79,264,573, 7 genes: AC009145.3, AC009145.1, AC009145.2, AC092376.2, AC092376.3, AC092376.1, RNA5SP431.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 279 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:151,239,967–151,358,559, 1 gene, copy number 5 (within-gene range 2–5): AKAP12.
- chr6:151,298,841–151,621,193, 9 genes, copy number 5: RNY4P20, RN7SKP268, ZBTB2, Y_RNA, RMND1, HSPA8P15, ARMT1, CCDC170, RNU6-813P.
- chr8:120,445,400–135,742,495, 229 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:135,977,329–136,295,232, 2 genes, copy number 6 (within-gene range 4–6): AC103955.1, AC023781.1.
- chr17:76,274,049–76,781,449, 38 genes, copy number 5 (within-gene range 2–5): QRICH2, PRPSAP1, Y_RNA, RNU6-24P, AC090699.1, SPHK1, UBE2O, RPL7P49, AANAT, RHBDF2, CYGB, PRCD, AC015802.4, AC015802.3, AC015802.5, SNHG16, SNORD1C, SNORD1B, SNORD1A, AC015802.6, ST6GALNAC2, AC015802.1, AC015802.2, AC015802.7, ST6GALNAC1, RNU6-227P, AC005837.1, MXRA7, RNY4P36, AC005837.4, JMJD6, AC005837.3, METTL23, AC005837.2, SRSF2, MFSD11, MIR636, RNU6-97P.

Autosomal genes at a single copy (total copy number 1): 15,119. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
